Surgical pathology report (de-identified scan), TCGA case TCGA-4Z-AA89, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-4Z-AA89-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

ICD-O-3
Carcinoma, urothelial papillary
cctf 8130/3
Site: Bladder trigone C67.0
path
Bladder NOS C67.9
9/23/18/14

PATHOLOGY REPORT:

PRIMARY SITE: Bladder

1 - "Cistoprostatectomy":

. High grade papillary urothelial carcinoma infiltrating all the wall until the prostate.
Left ureteral margin with focal urothelial carcinoma in situ
Right ureteral margin uninvolved by neoplasia

Right and left seminal vesicles uninvolved by neoplasia.
Right and left vas deferens uninvolved by neoplasia.

2- Left obturator lymph nodes
Absence of neoplasia (0/3)

3- Left iliac lymph nodes
Absence of neoplasia (0/2)

4- Right obturator lymph nodes
Absence of neoplasia (0/2)

5- Right iliac lymph nodes
Absence of neoplasia (0/3)

Source: NCI Genomic Data Commons file 4d3ade60-5be0-47e8-9477-7355e247f712 (TCGA-4Z-AA89.5D5A2A97-F2B3-4EBE-BD57-C035D1710874.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).